TCGA case TCGA-34-5927 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18f18672-2a23-4e26-987b-38c454ff46c7

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.8 years (25,857 days); Year of diagnosis: 2009; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,361 days (3.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 292 days; Days to treatment end: 385 days (1.1 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 71.5 years (26,102 days); Days to diagnosis: 245 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 245 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 245 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 941 days (2.6 years); Disease response: With Tumor.
- Days to follow up: 1,361 days (3.7 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 698.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-34-5927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-34-5927-01A-01-TS1: Section location: Top; Percent tumor cells: 54; Percent tumor nuclei: 70; Percent normal cells: 32; Percent necrosis: 14; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide TCGA-34-5927-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 43; Percent necrosis: 7; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 15; Percent neutrophil infiltration: 0.
- Sample TCGA-34-5927-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,361 days; disease-specific survival: no event (censored), 1,361 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 245 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-34-5927-01A-11D-1816-01): tumor purity 0.77, ploidy 1.77, whole-genome doublings 0.
